Somatic mutation profile of tumor specimen BA2872D (aliquot aq-BA2872D) from BEATAML1.0 case 2415, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.7 years (23,989 days).
Specimen BA2872D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56663923-dfed-4ba0-8b54-b35d268f2d8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2142D (Solid Tissue Normal), aliquot aq-BA2142D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cc84fc2-c3a6-47ae-8d84-0801bd746b2c

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LMBRD2 | c.536G>T p.W179L | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as COSV99682487; called by muse, mutect2
- CHD1 | c.3454G>T p.A1152S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- CLIP4 | c.1166-2A>G p.X389_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- FMO1 | c.1157C>A p.A386D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TEX14 | c.1203-1G>T p.X401_splice (on ENST00000240361 / NM_001201457.2; = p.X395_splice on NM_031272.5) | Splice Site (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
